Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24V, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24V-01A (Primary Tumor).

Final Diagnosis

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade II (of III) [tubules 2/3, nuclei 2/3, mitoses 2/3; Nottingham score 7/9], forming a mass (2.4 x 1.7 x 1.6 cm) [AJCC pT2]. Biopsy site changes are present. Ductal carcinoma in situ, solid and micropapillary type, intermediate nuclear grade, comprising 5-25% of the tumor mass. Angiolymphatic invasion is identified. All surgical resection margins, after re-excision of the medial margin, are negative for tumor (minimum tumor free margin, 1.0 cm, inferior margin).

Lymph nodes, right axillary sentinel Nos. 1 and 2, sentinel biopsy: A single (1 of 2) axillary sentinel lymph node is positive (for micrometastasis [AJCC pN1mi(sn)]), with 2 metastases, the largest measuring 1.0 mm and smallest 0.5 mm.

Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9
4/25/11

Source: NCI Genomic Data Commons file 111bf3ba-7c79-427f-b9c5-30b61f393fd5 (TCGA-AR-A24V.468CD293-C9F7-43C6-A40A-18FCDD22F6AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).